Surgical pathology report (de-identified scan), TCGA case TCGA-DG-A2KJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DG-A2KJ-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation	Fresh Frozen	
Site of Primary (Event)	Cervical	
Site of Tissue	cervix	ICD-0-3
Year of Sample Collection		carcinoma, squamous cell,
Age at Sample Collection (yrs)		nonkeratinizing, NOS 8072/3
Sample Comments		Site: cervix, NOS C53.9
Days to Procedure Date	0	lw 8/23/11
Days to Diagnosis	18	
Type of Procedure	Surgical resection	
Site of Primary (Histology)	Cervix	
Bilateral Disease	NO	
Tumour Size (cm)	2.8999999999999999	
Histology	Squamous cell carcinoma, nonkeratinizing	
Grade/Differentiation	N/A	
Pathological T	T1b	
Pathological N	N1	
Number of Nodes Sampled	1	
Number of Nodes Positive	23	
Clinical M	M0	
Histology Comments	Possible lymphovascular invasion is seen. Report states grade 3/3. All resection margins are clear.	

Source: NCI Genomic Data Commons file 19649d16-9426-48f1-b914-2ddb7287bd94 (TCGA-DG-A2KJ.F5EBC22F-D2D9-4944-9A24-390811798F5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).